Surgical pathology report (de-identified scan), TCGA case TCGA-KK-A8II, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-KK-A8II-01A (Primary Tumor).

[page 1 of 4]
Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

- (A) LEFT EXTERNAL, INTERNAL, HYPOGASTRIC AND OBTURATOR LYMPH NODES:
Nine lymph nodes, no tumor present.
- (B) RIGHT EXTERNAL, INTERNAL, HYPOGASTRIC AND OBTURATOR LYMPH NODES:
Ten lymph nodes, no tumor present.
Focal cortical expansion consistent with reactive changes. . (See comment)
- (C) SYMPHYSIS PUBIC BONE:
Supplemental report to follow.
- (D) PROSTATE AND SEMINAL VESICLES:
Supplemental report to follow.

Entire report and diagnosis completed by

COMMENT

Because of the presence of some cortical expansion in one pf the lymph nodes (B8) of specimen B , the lymph nodes were reviewed by Dr. from : Immunoperoxidase studies (L26,CD5 and CD43) are within limits and do not support a diagnosis of lymphoma. The changes are considered reactive.

ICD-O-3
Adenocarcinoma, acinar & ductal
Site: Prostate NOS 8500/3
C61.9
JW 11/24/13

GROSS DESCRIPTION

(A) LEFT EXTERNAL, INTERNAL, HYPOGASTRIC AND OBTURATOR LYMPH NODES - A tan-yellow irregular fragment of adipose tissue (6.8 x 3.5 x 1.5 cm). Thirteen possible lymph nodes are found ranging in size from 0.4 x 0.3 x 0.2 cm to 3.6 x 1.7 x 1.0 cm.

SECTION CODE: A1, four possible lymph nodes; A2, four possible lymph nodes; A3, two possible lymph nodes; A4, one bisected possible lymph node; A5, one bisected possible lymph node; A6-A7, one trisected possible lymph node.

(B) RIGHT EXTERNAL, INTERNAL, HYPOGASTRIC AND OBTURATORY LYMPH NODES - A tan-yellow irregular fragment of adipose tissue (5.0 x 4.5 x 1.8 cm). Ten possible lymph nodes are found ranging in size from 0.3 x 0.3 x 0.2 cm to 8.0 x 2.3 x 0.8 cm.

SECTION CODE: B1-B2, three possible lymph nodes in each cassette; B3, two possible lymph nodes; B4-B7, one serially sectioned possible lymph node; B8-B11, one serially sectioned possible lymph node.

(C) SYMPHYSIS PUBIC BONE - Multiple fragments of bone and admixed soft tissue (5.0 x 3.0 x 1.0 cm in aggregate). Remainder of the specimen is submitted for further histologic processing to the bone lab.

SECTION CODE: C1-C3, entire soft tissue.

CLINICAL HISTORY

None given.

CONSULTANT(S)

[page 2 of 4]
[REDACTED]

Specimen Date/Time: .

SNOMED CODES

T-C4600, M-00110

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Released by:

Start of ADDENDUM

[page 3 of 4]
Specimen Date/Time:

ADDENDUM

Addendum completed by

DIAGNOSIS

(C) SYMPHYSIS PUBIC BONE:

Bone with nonspecific reactive changes.

No tumor present.

(D) PROSTATE AND SEMINAL VESICLES:

PROSTATIC ADENOCARCINOMA, MIXED DUCTAL AND ACINAR TYPES, GLEASON SCORE 9 (4 + 5).
(SEE COMMENT)

TUMOR EXTENDING FOCALLY INTO EXTRAPROSTATIC TISSUE.

Margins of resection, free of tumor.

Prostatic intraepithelial neoplasia (PIN), high grade.

Right and left seminal vesicles, no tumor present.

Segments of right and left vasa deferentia, no tumor present.

COMMENT

The prostate gland contains two separate foci of prostatic adenocarcinoma, one in the peripheral zone and one in the transition zone. The dominant tumor focus is located in the left anterolateral, left lateral, left posterolateral, left posterior, mid posterior, right posterior, right posterolateral and right lateral peripheral zone. This tumor focus measures approximately 4.5 x 1.5 cm in the largest cross sectional dimension and it is present in four cross sections and extensively in the apical region. In the right posterolateral aspect of the prostate, tumor extends along nerve trunks into extraprostatic tissue. Extraprostatic extension is present in two sections. The length of extraprostatic tumor is less than 2.0 mm. The margins of resection are free of tumor. This tumor exhibits marked perineural invasion including nerve trunks present at the edge between the prostate and extraprostatic tissue. No other areas of unequivocal extraprostatic extension are identified. The second tumor focus is located in the transition zone, exclusively in the anterior and right apical region. This tumor focus measures 0.5 x 0.2 cm in the largest cross sectional dimension and it is present in three apical sections. This tumor focus is of lower histologic grade (Gleason score 6/3 + 3) and it is confined to the prostate.

The diagnosis for the symphysis pubic bone (part C) reflects the opinion of

from the section of orthopedic pathology.

GROSS DESCRIPTION

C) SYMPHYSIS PUBIC BONE - Multiple fragments of bone and admixed soft tissue (5.0 x 3.0 x 1.0 cm in aggregate). Remainder of the specimen is submitted for further histologic processing to the bone lab.

SECTION CODE: C1-C3, entire soft tissue. C4-C7, representative sections of the bone.

(D) PROSTATE AND SEMINAL VESICLES - A specimen consisting of a prostate, attached right and left seminal vesicles and attached segments of right and left vasa deferentia.

The prostate gland (4.5 x 3.4 x 3.9 cm, 37.5 gm, post fixation) has the usual shape. The soft tissue present along the right and left posterolateral aspects of the prostate appears symmetrical. The tumor is palpated on the right posterolateral and left posterolateral aspects of the prostate. Serial cross sections after fixation demonstrate a firm area consistent with tumor in the left peripheral zone of the first to the third cross sections.

[page 4 of 4]
Specimen Date/Time:

The seminal vesicles and segments of vasa deferentia are grossly free of tumor.

SECTION CODE: D1-D3, right seminal vesicle and segment of right vas deferens from the base towards the tip; D4, D5, left seminal vesicle and segment of left vas deferens from the base towards the tip; D6, prostatic base, right border; D7-D9, prostatic base, right posterior border; D10-D14, prostatic base, central portion; D15, D16, prostatic base, left border; D17-D19, prostatic base, left posterior border; D20, D21, apex anterior; D22, D23, apex left; D24-D26, apex posterior; D27, D28, apex right; D29-D47, sections of the four cross sections of the prostate according to specimen radiograph.

The anterior aspect of the prostate is inked in green, left surface in red, right surface in yellow and posterior surface in black. Orange ink (D39) denotes surfaces which do not represent the true margin of resection.

CONSULTANT(S)

SNOMED CODES

T-92000, M-Y1973

Released by:

-----END OF REPORT-----

Source: NCI Genomic Data Commons file 3e3ff47f-5704-4675-afe9-6d040053cfbd (TCGA-KK-A8II.0C940BA1-22F7-412D-AD58-84B950157601.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).